Gene-level copy-number profile of tumor specimen AP-5L2V-WM from APOLLO case AP-5L2V, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3.
Specimen AP-5L2V-WM: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 79923a95-87ad-4548-8bcf-3710e188942a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-5L2V-MN (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,893 have no estimate.
https://portal.gdc.cancer.gov/files/76d0b408-d4b8-4f16-a745-54e468a8983a

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 530; copy number 1: 84; copy number 2: 110; copy number 3: 14,192; copy number 4: 10,681; copy number 5: 15,117; copy number 6: 11,537; copy number 7: 5,271; copy number 8: 436; copy number 9: 583; copy number 10: 61; copy number 11: 2; copy number 12: 20; copy number 13: 2; copy number 15: 18; copy number 18: 3; copy number 20: 8; copy number 21: 7; copy number 24: 4; copy number 26: 8; copy number 27: 3; copy number 29: 4; copy number 32: 1; copy number 35: 5; copy number 40: 21; copy number 55: 3; copy number 56: 13; copy number 72: 2; copy number 84: 4.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,895,502–89,960,754, 8 genes: IGKV1D-35, IGKV3D-34, IGKV1D-33, IGKV1D-32, IGKV3D-31, IGKV2D-30, IGKV2D-29, IGKV2D-28.
- chr5:69,985,204–70,132,973, 6 genes: CDH12P2, SERF1B, SMN2, AC140134.1, NAIPP2, CDH12P3.
- chr6:29,887,294–29,934,286, 8 genes: AL645929.1, HLA-H, HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K, HLA-U.
- chr9:64,621,560–64,889,063, 9 genes: AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2, BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 128 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:31,268,749–31,415,315, 17 genes, copy number 15 (within-gene range 5–15): HLA-C, USP8P1, RPL3P2, WASF5P, LINC02571, AL671883.1, HLA-B, MIR6891, AL671883.2, DHFRP2, AL671883.3, RNU6-283P, FGFR3P1, ZDHHC20P2, HLA-S, AL645933.2, MICA.
- chr6:31,402,152–31,402,250, 1 gene, copy number 15 (within-gene range 5–15): Y_RNA.
- chr12:10,750,188–11,196,996, 30 genes, copy number 12–72: LINC02366, HSPE1P12, TAS2R7, TAS2R8, TAS2R9, PRH1, TAS2R10, AC006518.1, PRR4, AC018630.4, AC006518.2, TAS2R13, PRH2, TAS2R14, TAS2R15P, TAS2R50, TAS2R20, TAS2R19, TAS2R31, TAS2R63P, TAS2R46, TAS2R64P, TAS2R43, AC018630.1, TAS2R30, AC134349.2, AC134349.1, SMIM10L1, TAS2R42, AC244131.1.
- chr12:24,212,421–27,014,434, 56 genes, copy number 13–84: MIR920, SOX5-AS1, LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1, ITPR2, AC055720.2, RNA5SP354, AC023051.1, AC023051.2, INTS13, FGFR1OP2, TM7SF3, AC024896.1.
- chr12:32,100,485–32,383,633, 5 genes, copy number 35 (within-gene range 9–35): AC048344.3, AC048344.1, BICD1, AC048344.4, AC016954.1.
- chr12:32,790,755–32,896,777, 1 gene, copy number 11 (within-gene range 9–11): PKP2.
- chr12:32,863,118–32,863,433, 1 gene, copy number 11: RPL35AP27.
- chr12:33,454,345–33,455,452, 1 gene, copy number 32: AC016956.1.
- chr12:39,626,167–39,908,300, 1 gene, copy number 18 (within-gene range 5–18): C12orf40.
- chr12:39,819,750–39,819,883, 1 gene, copy number 18 (within-gene range 5–18): AC121336.1.
- chr12:106,301,929–106,987,160, 13 genes, copy number 12 (within-gene range 5–12): TCP11L2, POLR3B, AC079385.1, RFX4, AC079385.2, AC079385.3, RIC8B, AC007695.1, EEF1B2P4, RPL30P12, AC007541.1, TMEM263, MTERF2.
- chr12:107,093,298–107,123,314, 1 gene, copy number 18 (within-gene range 5–18): AC078929.1.

Autosomal genes at a single copy (total copy number 1): 71. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
